TARGET case TARGET-15-SJMPAL043769 — Acute Lymphoblastic Leukemia - Phase III (TARGET-ALL-P3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/2b7cf043-588d-4d54-ba44-ae512095f572

Demographics
Sex at birth: female; Age at index: 15 years; Vital status: Dead; Days to death: 572 days (1.6 years).

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 15.7 years (5,752 days); Year of diagnosis: 2013; Days to last follow up: 572 days (1.6 years).

Follow-up (1 entry)
- Days to follow up: 572 days (1.6 years); Event-free: no event (relapse, second malignancy or death) recorded through day 572; Year of follow up: 2014.

Molecular and laboratory tests (laboratory values one line per visit day)
- Day 0: Leukocytes 32.7 ×10³/µL.

Biospecimens (3 samples)
- Samples TARGET-15-SJMPAL043769-03A.1, TARGET-15-SJMPAL043769-03B (2 with the same recorded description): Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
- Sample TARGET-15-SJMPAL043769-10A.1: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Phase_III_20230725.xlsx:
- Overall Survival Time in Days: 572
- Protocol: AIEOP
- WBC at Diagnosis: 32.7
- Initial Therapy: AML
- WHO ALAL Classification: AUL
- WHO Dx: AUL
